Gene-level copy-number profile of specimen HCM-BROD-0559-C16-85M from HCMI case HCM-BROD-0559-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 24.3 years (8,881 days).
Specimen HCM-BROD-0559-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f59164ac-7e89-4c65-b6cf-b2bb6f0c51ee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0559-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/4ce5feea-5e06-4cc0-9cb3-e14b5fa090d8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 18,734; copy number 3: 10,835; copy number 4: 20,378; copy number 5: 3,475; copy number 6: 5,048; copy number 8: 4; copy number 10: 78; copy number 11: 11; copy number 12: 40; copy number 14: 36; copy number 15: 132; copy number 22: 1; copy number 23: 53; copy number 32: 8; copy number 42: 11; copy number 44: 1; copy number 48: 18; copy number 63: 25; copy number 65: 7; copy number 153: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 432 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,268,200–150,995,634, 36 genes, copy number 14 (within-gene range 5–14): C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9.
- chr1:202,168,051–204,435,846, 77 genes, copy number 15–48 (within-gene range 2–48) (broad region; genes not listed).
- chr1:218,459,265–225,999,343, 140 genes, copy number 12–153 (broad region; genes not listed).
- chr1:230,314,490–232,630,571, 46 genes, copy number 15: PGBD5, LINC01737, AL158214.1, COG2, AL158214.2, AGT, AL512328.1, CAPN9, RNA5SP79, AL118511.2, C1orf198, AL118511.1, AL118511.4, AL118511.3, RN7SL837P, TTC13, ARV1, FAM89A, MIR1182, AL732414.1, AL109810.1, TRIM67, TRIM67-AS1, C1orf131, GNPAT, RNA5SP80, EXOC8, SPRTN, AL117352.1, EGLN1, AL445524.2, SNRPD2P2, AL445524.1, TSNAX, TSNAX-DISC1, LINC00582, DISC1, RNU5A-5P, AL136171.2, AL136171.1, DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2.
- chr10:120,069,980–122,643,736, 37 genes, copy number 10–44: AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1.
- chr12:24,212,421–25,250,936, 22 genes, copy number 10: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr13:71,913,704–75,549,439, 42 genes, copy number 10: RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6.
- chr17:38,297,023–38,605,952, 7 genes, copy number 65: MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1.
- chr17:41,717,742–41,734,644, 1 gene, copy number 63 (within-gene range 2–63): HAP1.
- chr17:41,730,127–41,930,542, 10 genes, copy number 63: RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2.
- chr17:42,567,072–42,699,993, 14 genes, copy number 63: MLX, PSMC3IP, AC067852.5, RETREG3, AC067852.4, TUBG1, ATP5MGP7, HMGB3P27, TUBG2, PLEKHH3, CCR10, AC100793.2, CNTNAP1, AC100793.3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
